Somatic mutation profile of tumor specimen TCGA-C5-A7X8-01A (aliquot TCGA-C5-A7X8-01A-11D-A36J-09) from TCGA case TCGA-C5-A7X8, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 35.5 years (12,977 days).
Specimen TCGA-C5-A7X8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b85a7e6-48e6-4ffd-b9a0-e0ab5bb87d61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A7X8-10A (Blood Derived Normal), aliquot TCGA-C5-A7X8-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45b87833-fd5c-430f-866b-b0297097ba30

The open-access MAF lists 71 somatic variants for this specimen: 47 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 40, Silent 24, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF4 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.472); catalogued as COSV99347885; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5602C>T p.R1868W | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV51851988; called by muse, mutect2
- ANKRD30A | c.739A>G p.T247A (on ENST00000611781; = p.T191A on NM_052997.2) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV100652618; called by muse, varscan2
- ASPM | c.2939G>A p.R980Q | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs751556744, COSV99659242; called by muse, mutect2, varscan2
- BICC1 | c.2491G>A p.A831T | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs757528583, COSV99570044; called by muse, mutect2, varscan2
- BRD7 | c.992G>C p.R331T | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.179); catalogued as COSV101164494; called by muse, mutect2, varscan2
- CATSPERB | c.2163G>C p.W721C | Missense Mutation (SNP) | VAF 82/183 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV56425726; called by muse, mutect2, varscan2
- CCDC171 | c.2177C>T p.S726F | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs765430714, COSV99899611; called by muse, mutect2, varscan2
- CCDC88A | c.4528G>C p.E1510Q (on ENST00000436346 / NM_001365480.1; = p.E1482Q on NM_018084.5) | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV99709535; called by muse, mutect2, varscan2
- CLSPN | c.4002C>G p.F1334L | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99230085; called by muse, mutect2, varscan2
- CUL2 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV101038982; called by muse, mutect2, varscan2
- DCAF12L2 | c.970G>A p.G324S | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63584262; called by muse, mutect2, varscan2
- DIS3L2 | c.2376G>C p.Q792H | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99804984; called by muse, mutect2, varscan2
- DMD | c.8852G>A p.R2951H | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs72466567, COSV58933390; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- EEF2K | c.92G>A p.S31N | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.968); catalogued as COSV99532401; called by muse, mutect2, varscan2
- FAM204A | c.650+1G>T p.X217_splice | Splice Site (SNP) | VAF 20/59 reads (34%) | catalogued as COSV100977404; called by muse, mutect2
- FBXO42 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as rs760530903, COSV65046371; called by muse, mutect2, varscan2
- FBXO42 | c.1393C>G p.P465A | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV100981591; called by muse, mutect2, varscan2
- HLA-B | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.952); catalogued as COSV101317736, COSV69523034; called by muse, mutect2, varscan2
- HLA-B | c.896-1G>C p.X299_splice | Splice Site (SNP) | VAF 44/150 reads (29%) | catalogued as COSV69520575, COSV69520821; called by muse, varscan2
- KHDC4 | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100850747; called by muse, mutect2, varscan2
- KIF7 | c.3771_3772del p.A1258Pfs*27 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | catalogued as rs770804978; called by pindel, varscan2*
- LAMB2 | c.1816C>T p.Q606* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100564927; called by muse, mutect2, varscan2
- LTN1 | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100797828; called by muse, mutect2, varscan2
- METTL7A | c.523C>A p.H175N | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100153611; called by muse, mutect2, varscan2
- MYH13 | c.1836G>T p.Q612H | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52822295, COSV99351623; called by muse, mutect2, varscan2
- NAV1 | c.3524G>A p.R1175Q | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); catalogued as rs376014588, COSV99818921; called by muse, mutect2, varscan2
- OPN5 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV99789660; called by muse, varscan2
- PCNX4 | c.1971G>C p.L657F (on ENST00000406854 / NM_001330177.2; = p.L423F on NM_022495.5) | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100469646, COSV100469930; called by muse, mutect2, varscan2
- PDE1C | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 25/98 reads (26%) | catalogued as rs754659378, COSV58525641, COSV58527623; called by muse, mutect2, varscan2
- PLXND1 | c.3725C>T p.A1242V | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs781053507, COSV60714467; called by muse, mutect2, varscan2
- PPEF1 | c.1624T>C p.S542P | Missense Mutation (SNP) | VAF 15/265 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100583449, COSV100583998; called by muse, mutect2
- PSG1 | c.261A>T p.E87D | Missense Mutation (SNP) | VAF 17/302 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99738391; called by muse, mutect2
- RNF139 | c.1332C>A p.F444L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV99413103; called by muse, mutect2, varscan2
- RPAP1 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100426815, COSV58542669; called by muse, mutect2, varscan2
- RTN4 | c.2948C>T p.S983F | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV100462577, COSV100464078; called by muse, mutect2, varscan2
- SEMA3C | c.251A>C p.Q84P | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV99542150; called by muse, mutect2, varscan2
- SFRP4 | c.1017G>C p.K339N | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as rs1237455127, COSV101460865, COSV71412408; called by muse, mutect2, varscan2
- SPG11 | c.4643C>A p.P1548Q | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55993626, COSV99967798; called by muse, mutect2, varscan2
- SYTL2 | c.472A>T p.R158W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374756400; called by muse, mutect2, varscan2
- TRAV16 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs747312541; called by muse, mutect2, varscan2
- TRIM39 | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV100935579; called by muse, mutect2, varscan2
- TSPEAR | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs200086668, COSV59964021; called by muse, mutect2, varscan2
- VPS13D | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1166466612, COSV100691962; called by muse, mutect2
- ZNF568 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100451099; called by muse, mutect2, varscan2
- GHDC | c.728_748del p.A243_R249del | In Frame Del (DEL) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- MTMR9 | c.629dup p.N210Kfs*26 | Frame Shift Ins (INS) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- AGXT2 | c.198C>A p.V66= | Silent (SNP) | VAF 24/166 reads (14%) | catalogued as COSV99183684; called by muse, mutect2, varscan2
- ARSJ | c.243C>T p.I81= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV100192349; called by muse, mutect2, varscan2
- BAP1 | c.1335C>T p.I445= | Silent (SNP) | VAF 53/66 reads (80%) | catalogued as COSV99963197; called by muse, mutect2, varscan2
- CCDC47 | c.969C>T p.H323= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs1219135239, COSV99853911; called by muse, mutect2, varscan2
- CD200R1L | c.402C>T p.F134= | Silent (SNP) | VAF 9/174 reads (5%) | catalogued as COSV101236529; called by muse, mutect2
- CFAP61 | c.1812C>T p.Y604= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs766919114, COSV55638950; called by muse, mutect2, varscan2
- FLYWCH1 | c.33C>T p.G11= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as rs972819553, COSV54145749; called by muse, mutect2, varscan2
- GPI | c.1614C>T p.H538= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs537943038, COSV99874822; called by muse, mutect2, varscan2
- GPRC6A | c.1707T>A p.T569= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV100113887; called by muse, mutect2, varscan2
- GRIN2B | c.3957G>A p.P1319= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as rs141730031; ClinVar: likely benign; called by muse, mutect2, varscan2
- HAUS1 | c.702G>A p.L234= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV99959309; called by muse, mutect2, varscan2
- HTR1B | c.714G>T p.R238= | Silent (SNP) | VAF 55/94 reads (59%) | catalogued as COSV100885295; called by muse, mutect2, varscan2
- IQCA1 | c.1578G>A p.L526= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV54514613, COSV99608265; called by muse, mutect2, varscan2
- IQCN | c.1842G>A p.A614= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs756846594, COSV66573601; called by muse, mutect2, varscan2
- OPN5 | c.651C>T p.F217= | Silent (SNP) | VAF 46/102 reads (45%) | catalogued as COSV99789663; called by muse, varscan2
- OTOGL | c.894C>T p.L298= (on ENST00000547103; = p.L289= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs377112652; called by muse, varscan2
- PHKA2 | c.1989T>C p.Y663= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as rs770108234, COSV101176540; ClinVar: likely benign; called by muse, mutect2, varscan2
- POLR2A | c.1326C>T p.T442= | Silent (SNP) | VAF 42/63 reads (67%) | catalogued as rs146006267, COSV100496144; called by muse, mutect2, varscan2
- PRG2 | c.447C>T p.V149= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100314820; called by muse, mutect2, varscan2
- RBM10 | c.1917G>A p.K639= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV100237058; called by muse, mutect2, varscan2
- RBM48 | c.183A>G p.E61= | Silent (SNP) | VAF 59/115 reads (51%) | catalogued as rs754315226, COSV99719999; called by muse, mutect2, varscan2
- RPL5 | c.330C>T p.L110= | Silent (SNP) | VAF 46/80 reads (58%) | catalogued as rs1441314275, COSV100240215, COSV59872820; called by muse, mutect2, varscan2
- SI | c.5047C>T p.L1683= | Silent (SNP) | VAF 37/130 reads (28%) | catalogued as COSV100013352, COSV52270587; called by muse, mutect2, varscan2
- ZNF3 | c.198G>A p.K66= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as rs1439709519, COSV99447029; called by muse, mutect2, varscan2
